Surgical pathology report (de-identified scan), TCGA case TCGA-ZM-AA0H, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Ulm, specimen TCGA-ZM-AA0H-01A (Primary Tumor).

ICD O-3
Seminoma NOS 9061/3
Site: Testis NOS C62.9
GJ 3/3/14

Date of procurement: . . .

Pathological diagnosis: Testicular Seminoma

Description: A testicle with tumor, size 8.5:7.5 cm, with 9 cm long funiculus was received. We see on the cut that the whole testicle is imbued with tumor and on the capsule we see 6.5 cm long surgical cut with sutures. On the cut, the tumor is white, soft and partially necrotic.

Histologically, the tumor is made of solid seats and tumor cell traces with round and oval bright nuclei with pronounced smaller nuclei with medium abundant bright and pink cytoplasm. Within the tumor, using high microscope magnification, we can see 3-4 mitoses. Surrounding tumor seats we find connecting tissue containing meager to medium abundant lymphocyte infiltrate.

The tumor is present in lumens of two blood vessels within funiculus next to the testicle, but it is not present at funiculus plane resection.

The tumor does not infiltrate testicular capsule.

Reviewed (initials):	DATE REVIEWED:	

hw 12/19/13

Source: NCI Genomic Data Commons file 8951208d-f5d6-4616-a752-62bd32e7c625 (TCGA-ZM-AA0H.379CA566-4F13-4FF6-8D90-60175AAC9362.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).